Somatic mutation profile of tumor specimen TARGET-30-PAREAG-01A (aliquot TARGET-30-PAREAG-01A-01D) from TARGET case TARGET-30-PAREAG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.7 years (2,091 days).
Specimen TARGET-30-PAREAG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd511ff-e662-4a74-83c0-d5b7097e278a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAREAG-10A (Blood Derived Normal), aliquot TARGET-30-PAREAG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eac0ee6-31bf-4a40-b650-2e2d0aad9a56

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 29, Silent 6, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV57048636; called by muse, mutect2, varscan2
- ANKRD11 | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56374901; called by muse, mutect2, varscan2
- COLQ | c.1195+1G>A p.X399_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as rs755782087, CS000217, CS080658, COSV67524367; called by muse, varscan2
- DNASE1L1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50011524; called by muse, mutect2, varscan2
- FNIP1 | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57201877; called by muse, mutect2, varscan2
- GRID2 | c.2473G>T p.A825S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.025); catalogued as COSV56173397, COSV56284077; called by muse, mutect2, varscan2
- IGHV1-46 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs781888621; called by muse, mutect2, varscan2
- ISCA2 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.74); catalogued as COSV53144542; called by muse, mutect2, varscan2
- KLHL8 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs751031930, COSV56750117; called by muse, varscan2
- MEIOC | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV63441781; called by muse, mutect2, varscan2
- NCKAP1L | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV53208771, COSV53213705; called by muse, mutect2, varscan2
- NR3C2 | c.1679G>T p.W560L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as CM070231, COSV61001623; called by muse, mutect2, varscan2
- OR10C1 | c.801C>A p.Y267* (on ENST00000622521; = p.Y265* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 16/232 reads (7%) | catalogued as COSV65822313, COSV65824117, COSV99058448; called by muse, mutect2
- PRDM1 | c.1012T>C p.S338P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV64847434; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.378G>T p.E126D (on ENST00000421990 / NM_001136042.2; = p.E108D on NM_025267.3) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.044); catalogued as COSV64185008; called by muse, mutect2, varscan2
- PVALB | c.162C>G p.D54E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53413508; called by muse, mutect2, varscan2
- SF1 | c.1430T>A p.M477K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV57118242; called by muse, mutect2, varscan2
- SLITRK4 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.093); catalogued as COSV62026680; called by muse, mutect2, varscan2
- ZCCHC14 | c.2723G>A p.C908Y (on ENST00000268616; = p.C1045Y on NM_015144.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51891249; called by muse, mutect2, varscan2
- ZNF136 | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV59712040; called by muse, mutect2, varscan2
- ZNF264 | c.1251C>A p.H417Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54044561; called by muse, mutect2, varscan2
- COL4A1 | c.4004G>A p.G1335D | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT2 | c.2149C>T p.H717Y | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- HGFAC | c.1463A>T p.Y488F | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.303); called by muse, mutect2
- IGKV1-5 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LLGL1 | c.2258T>A p.F753Y | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MGAT4A | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- OR13C3 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCDHB13 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- POLI | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.261); called by muse, mutect2
- TBC1D16 | c.1072A>T p.M358L | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- ARHGEF11 | c.3741C>T p.P1247= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1246056300, COSV59359493; called by muse, mutect2, varscan2
- CMTM5 | c.322C>T p.L108= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59308596; called by muse, mutect2
- FOXD4L1 | c.657T>G p.P219= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV52077067; called by muse, mutect2, varscan2
- MBD5 | c.444A>T p.V148= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV68699281; called by muse, mutect2, varscan2
- SPTBN2 | c.4647G>A p.E1549= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1300407242, COSV59463010; called by muse, mutect2, varscan2
- SVEP1 | c.6237A>T p.I2079= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52845191; called by muse, mutect2, varscan2
